Somatic mutation profile of tumor specimen 0DEK1L from CCDI case PBBPWG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.7 years (3,898 days).
Specimen 0DEK1L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12738757-580b-4301-ae65-7251e523d757.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEJZO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c54f79cd-a053-412f-9e63-49607e2258d8

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 5, In Frame Ins 1, Nonsense Mutation 1, Intron 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 1481/1646 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs769696078, COSV51770322, COSV99297135; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 663/1176 reads (56%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.2702G>T p.C901F | Missense Mutation (SNP) | VAF 383/987 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55881149; called by muse, mutect2, varscan2
- BTNL9 | c.1330G>A p.V444M | Missense Mutation (SNP) | VAF 139/340 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs766239405, COSV59793897; called by muse, mutect2, varscan2
- DYRK1A | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 174/599 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as rs1270094743; called by muse, mutect2, varscan2
- GALNTL6 | c.1162G>A p.V388I | Missense Mutation (SNP) | VAF 259/729 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs750015890; called by muse, mutect2, varscan2
- KIAA1755 | c.1948G>A p.A650T | Missense Mutation (SNP) | VAF 285/1308 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1455198884, COSV54074885; called by muse, mutect2, varscan2
- KRT39 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 391/1002 reads (39%) | catalogued as rs866707936, COSV62917367; called by muse, mutect2, varscan2
- MXRA5 | c.3443G>A p.R1148Q | Missense Mutation (SNP) | VAF 343/977 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs759614028, COSV54236129; called by muse, mutect2, varscan2
- NINL | c.2633G>A p.R878H | Missense Mutation (SNP) | VAF 34/1288 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.099); catalogued as rs1038478506; called by muse, mutect2
- SMARCA1 | c.2851C>T p.R951C | Missense Mutation (SNP) | VAF 219/714 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs757864280, COSV64410619; called by muse, varscan2
- TRPV5 | c.365A>G p.H122R | Missense Mutation (SNP) | VAF 596/1510 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1345549566; called by muse, mutect2, varscan2
- DNAJC10 | c.660A>T p.R220S | Missense Mutation (SNP) | VAF 332/971 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- DPF1 | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 126/401 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- EGFR | c.2304_2305insCTGGACAGC p.S768_V769insLDS | In Frame Ins (INS) | VAF 238/1285 reads (19%) | called by mutect2, varscan2
- FFAR2 | c.613A>T p.I205F | Missense Mutation (SNP) | VAF 172/521 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- H4C5 | c.295T>C p.Y99H | Missense Mutation (SNP) | VAF 406/1107 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MMGT1 | c.247dup p.T83Nfs*12 | Frame Shift Ins (INS) | VAF 156/511 reads (31%) | called by mutect2, varscan2
- MTOR | c.7006C>G p.L2336V | Missense Mutation (SNP) | VAF 221/631 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE6A | c.2339T>C p.V780A | Missense Mutation (SNP) | VAF 353/967 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TACR3 | c.883A>G p.R295G | Missense Mutation (SNP) | VAF 233/713 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKRD33 | c.516G>A p.P172= (on ENST00000340970 / NM_001304459.2; = p.P297= on NM_182608.4) | Silent (SNP) | VAF 220/1028 reads (21%) | catalogued as rs201364500, COSV100001243; called by muse, mutect2, varscan2
- BPTF | c.4095G>A p.Q1365= | Silent (SNP) | VAF 436/1211 reads (36%) | called by muse, mutect2, varscan2
- CAMSAP3 | c.2193C>T p.P731= | Silent (SNP) | VAF 170/419 reads (41%) | catalogued as rs1343700273; called by muse, mutect2, varscan2
- GRIN3B | c.2220C>T p.N740= | Silent (SNP) | VAF 123/341 reads (36%) | catalogued as rs1457075815; called by muse, mutect2, varscan2
- LONRF3 | c.234G>A p.A78= | Silent (SNP) | VAF 320/939 reads (34%) | catalogued as COSV100504221; called by muse, mutect2, varscan2
- AC245748.1 | c.16-26562G>T | Intron (SNP) | VAF 275/818 reads (34%) | called by mutect2, varscan2
- MAGEB5 | c.*60dup | 3'UTR (INS) | VAF 66/164 reads (40%) | catalogued as rs988188991; called by mutect2, varscan2
